Somatic mutation profile of tumor specimen 0DIPLG from CCDI case PBBWEK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.1 years (780 days).
Specimen 0DIPLG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c20c1f23-1eb9-4ba8-afdb-32a2b87a9aba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIPKW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be446785-0e78-4474-a53d-9485dd40ccd1

The open-access MAF lists 10 somatic variants for this specimen: 5 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 3, 3'UTR 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AFF3 | c.1082C>T p.S361L | Missense Mutation (SNP) | VAF 22/789 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.284); catalogued as rs1391300641, COSV57855995; called by muse, mutect2
- SDK2 | c.5566C>T p.R1856C | Missense Mutation (SNP) | VAF 88/1170 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as rs371296779; called by muse, mutect2
- MBD2 | c.278G>A p.G93D | Missense Mutation (SNP) | VAF 97/554 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2
- TPTE2 | c.586C>T p.Q196* (on ENST00000400230 / NM_199254.2; = p.Q119* on NM_130785.3) | Nonsense Mutation (SNP) | VAF 51/426 reads (12%) | called by muse, mutect2, varscan2
- XYLB | c.1130T>A p.F377Y | Missense Mutation (SNP) | VAF 119/595 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ADAMDEC1 | c.390C>T p.I130= | Silent (SNP) | VAF 78/707 reads (11%) | catalogued as COSV56477193; called by muse, varscan2
- TRIM51GP | c.117C>T p.F39= | Silent (SNP) | VAF 144/929 reads (16%) | called by muse, varscan2
- USP17L7 | c.633C>T p.H211= | Silent (SNP) | VAF 22/238 reads (9%) | catalogued as rs745766893; called by muse, mutect2
- MLH3 | c.*70A>G | 3'UTR (SNP) | VAF 8/146 reads (5%) | called by muse, mutect2
- SPHKAP | c.*48G>C | 3'UTR (SNP) | VAF 35/236 reads (15%) | catalogued as COSV100764090; called by muse, mutect2, varscan2
